Surgical pathology report (de-identified scan), TCGA case TCGA-76-4929, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-4929-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right frontal lobe tumor: glioblastoma multiforme, grade IV of iv (who scale), see microscopic description
2. Right frontal lobe tumor: glioblastoma multiforme, grade IV of iv (who scale), see microscopic description

[REDACTED]
Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.
[REDACTED]

Microscopic Description:

The tumor consists of a moderately pleomorphic and infiltrative proliferation of astrocytic cells. The tumor appears biphasic with small cells and regions with larger cells containing more abundant eosinophilic cytoplasm. There are scattered mitoses, foci of endothelial proliferation and necrosis. Immunohistochemistry for GFAP is strongly positive in most of the larger tumor cells and a smaller proportion of the smaller cells. Immunohistochemistry for LCA is negative in tumor cells. The morphologic and immunohistochemical findings are diagnostic of a glioblastoma multiforme, grade IV of IV (WHO scale).

Frozen Section Diagnosis:

1. Right frontal lobe tumor: GBM

Clinical History and Diagnosis:

Right frontal tumor

[page 2 of 3]
Source of Specimen:

- 1: Right frontal lobe tumor
- 2: Right frontal lobe tumor

Gross Description:

1. Right frontal lobe tumor: Received fresh for frozen section processing are four fragments of tan heterogeneous soft tissue measuring 1.5 x 1 x 0.5 cm in aggregate. Approximately 50% of the specimen is frozen. Touch preparations are performed. The entire specimen is submitted in two cassettes.

2. Right frontal lobe tumor: Received in formalin are two fragments of irregular tan white soft tissue measuring 1 x 0.6 to 0.3 cm in aggregate. The entire specimen is submitted in one cassette.

Histology Laboratory
H&E

Part 2: Right frontal lobe tumor
UNSTAINED

[page 3 of 3]
[REDACTED]

Patient: [REDACTED]

IMMUNOPATHOLOGY REPORT

EVALUATION:

Immunohistochemistry for GFAP is strongly positive in most of the larger tumor cells and a smaller proportion of the smaller cells.

Immunohistochemistry for LCA is negative in tumor cells. See [REDACTED] for a complete description of the light microscopy.

[REDACTED]

Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Source: NCI Genomic Data Commons file 0ef03c00-bef5-46cb-91b0-752ebf461615 (TCGA-76-4929.65054AC8-F9AA-4342-9F18-81C15EFD6D81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).